Somatic mutation profile of tumor specimen TCGA-23-1111-01A (aliquot TCGA-23-1111-01A-01W-0639-09) from TCGA case TCGA-23-1111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.4 years (23,171 days).
Specimen TCGA-23-1111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a76b0916-87be-4dfa-844c-284d77a7e819.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1111-10C (Blood Derived Normal), aliquot TCGA-23-1111-10C-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904f2718-ff6b-4dd8-b935-3689fe00565b

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Nonsense Mutation 6, Intron 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 53/63 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH1L1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs369044554, COSV56411467, COSV56419494; called by muse, mutect2, varscan2
- ANKRD13C | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1206778274, COSV52034500, COSV99256312; called by muse, mutect2
- AP2M1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99490378; called by muse, mutect2
- ARID3B | c.1142C>A p.S381Y | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV60556710, COSV60557347; called by muse, mutect2, varscan2
- AXDND1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62640359; called by muse, mutect2, varscan2
- C1RL | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV56923773; called by muse, mutect2, varscan2
- CASQ2 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 4/90 reads (4%) | catalogued as COSV99797097; called by muse, mutect2
- CEP350 | c.6700G>T p.E2234* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV62599567, COSV62610671; called by muse, mutect2, varscan2
- CHAMP1 | c.2306G>C p.R769P | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63521905; called by muse, mutect2, varscan2
- CSMD3 | c.2078G>C p.G693A (on ENST00000297405 / NM_001363185.1; = p.G589A on NM_052900.3) | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV99826403; called by muse, mutect2
- CUL9 | c.1082G>A p.W361* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV52726113; called by muse, mutect2, varscan2
- DISP1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV99450150; called by muse, mutect2
- EPN3 | c.1152dup p.T385Hfs*20 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs760519306; called by pindel, varscan2
- FAM155B | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV52935390; called by muse, mutect2, varscan2
- FBXL17 | c.1694G>C p.C565S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100670633; called by muse, mutect2
- FCMR | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100892830; called by muse, mutect2
- GABRE | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV64819083; called by muse, mutect2, varscan2
- GIMAP2 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV56234648; called by muse, mutect2, varscan2
- GUCY1A1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649781; called by muse, mutect2, varscan2
- H2AC11 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs749587602, COSV60361760; called by muse, mutect2, varscan2
- HJURP | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100982558; called by muse, mutect2
- HTR1A | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.893); catalogued as COSV60499789; called by muse, mutect2, varscan2
- INPP5D | c.1906G>A p.E636K (on ENST00000445964 / NM_001017915.3; = p.E635K on NM_005541.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64035793; called by muse, mutect2, varscan2
- KBTBD6 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs929444810, COSV65270994; called by muse, mutect2, varscan2
- KCNN1 | c.412T>A p.Y138N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55837380; called by muse, mutect2, varscan2
- KIF18A | c.1025del p.T342Nfs*18 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as COSV54181597; called by mutect2, pindel, varscan2
- MAP4 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV64236671; called by muse, mutect2, varscan2
- MKI67 | c.5602G>A p.D1868N | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as COSV64073026; called by muse, mutect2, varscan2
- NALCN | c.4244C>G p.T1415R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51921944; called by muse, mutect2, varscan2
- NAV3 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.098); catalogued as COSV57065812; called by muse, mutect2, varscan2
- NCF2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320994851, COSV62314900; called by muse, mutect2, varscan2
- NLRP3 | c.284A>C p.D95A | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100275346; called by muse, mutect2
- NOTCH1 | c.6083G>A p.G2028D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485824; called by muse, mutect2
- OR2G6 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100598043, COSV58573681; called by muse, mutect2
- PER1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs897415567, COSV57917737; called by muse, mutect2, varscan2
- PITRM1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99828348; called by muse, mutect2
- PKP4 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs771934822, COSV101081177, COSV67676038; called by muse, mutect2, varscan2
- PTPRG | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55631696; called by muse, mutect2, varscan2
- RASIP1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as rs749645984, COSV55802663; called by muse, mutect2
- RGS7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.023); catalogued as COSV58532772, COSV58560969; called by muse, mutect2, varscan2
- RTL8B | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as COSV66954149; called by muse, mutect2, varscan2
- TMEM139 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60081524, COSV60083086; called by muse, mutect2, varscan2
- TMPO | c.1369A>T p.M457L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV54122328, COSV54124621; called by muse, mutect2, varscan2
- UBA7 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199791699, COSV61091332; called by muse, mutect2, varscan2
- USH2A | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs552928943, COSV56336342; called by muse, mutect2, varscan2
- VWF | c.6410C>A p.S2137Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as CD095419, COSV54613489; called by muse, mutect2, varscan2
- CARD6 | c.2192C>A p.S731Y | Missense Mutation (SNP) | VAF 16/576 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- IKZF2 | c.1408_1414delinsC p.A470_K472delinsQ | In Frame Del (DEL) | VAF 44/207 reads (21%) | called by pindel, varscan2*
- ASH1L | c.7128A>G p.Q2376= (on ENST00000368346 / NM_001366177.2; = p.Q2371= on NM_018489.3) | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as COSV64206046; called by muse, mutect2, varscan2
- CDSN | c.909T>G p.S303= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV52537453; called by muse, mutect2, varscan2
- FAM53C | c.849T>G p.T283= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV53510921; called by muse, mutect2, varscan2
- FBL | c.957G>A p.V319= | Silent (SNP) | VAF 6/190 reads (3%) | called by muse, mutect2
- GRIA1 | c.1914G>A p.L638= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV53592025; called by muse, mutect2, varscan2
- KCND2 | c.1134A>C p.P378= | Silent (SNP) | VAF 51/348 reads (15%) | catalogued as COSV58571822; called by muse, mutect2, varscan2
- LAMA1 | c.654C>T p.F218= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV101055262; called by muse, mutect2
- LGALS4 | c.669C>A p.I223= | Silent (SNP) | VAF 45/264 reads (17%) | catalogued as COSV57043031, COSV57044141; called by muse, mutect2, varscan2
- OR2J2 | c.441G>A p.A147= | Silent (SNP) | VAF 95/464 reads (20%) | catalogued as rs745677629, COSV65847784, COSV65848385; called by muse, mutect2, varscan2
- PGBD2 | c.1017G>A p.Q339= | Silent (SNP) | VAF 10/258 reads (4%) | catalogued as COSV61401502; called by muse, mutect2
- PRAMEF12 | c.1065A>G p.L355= | Silent (SNP) | VAF 54/270 reads (20%) | catalogued as COSV100743675, COSV63214831; called by muse, mutect2, varscan2
- RP1 | c.258T>G p.P86= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV55111901; called by muse, mutect2, varscan2
- SYNE2 | c.855C>T p.S285= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV58359497; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-407C>T | Intron (SNP) | VAF 42/204 reads (21%) | catalogued as rs755282692; called by muse, mutect2, varscan2
- TRAK1 | c.1963+255G>A | Intron (SNP) | VAF 58/168 reads (35%) | catalogued as rs374428098, COSV58256431; called by muse, mutect2, varscan2
